Somatic mutation profile of tumor specimen TCGA-FE-A233-01A (aliquot TCGA-FE-A233-01A-11D-A14W-08) from TCGA case TCGA-FE-A233, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 18.5 years (6,770 days).
Specimen TCGA-FE-A233-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6330a8fd-21b5-4a0e-bfb3-3a5c01ca5b4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A233-10A (Blood Derived Normal), aliquot TCGA-FE-A233-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/741041fe-96eb-4136-bdbb-0fec85f5c687

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH8 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs1161696522, COSV54854717, COSV54865566, COSV54902074; called by muse, mutect2
- LSAMP | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs765460014, COSV61304800; called by muse, mutect2, varscan2
- MAP3K15 | c.466C>A p.H156N | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as COSV58835267; called by muse, mutect2, varscan2
- MCMBP | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 8/124 reads (6%) | catalogued as COSV63510163; called by muse, mutect2
- OR10Z1 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63524896, COSV63525931; called by muse, mutect2
- RAD51AP1 | c.371G>A p.S124N (on ENST00000228843 / NM_001130862.2; = p.S107N on NM_006479.5) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57411396; called by muse, mutect2
- TMEM26 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV53263597; called by muse, mutect2, varscan2
- ITGBL1 | c.844C>A p.R282= | Silent (SNP) | VAF 78/192 reads (41%) | catalogued as COSV66010548, COSV66012407; called by muse, mutect2, varscan2
- KIF13A | c.4728G>A p.L1576= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV52460814; called by muse, mutect2
